Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A5EI, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A5EI-01A (Primary Tumor).

[page 1 of 6]
Patient: [Redacted]

Referring Physician:

Gender: F

Ref#:

Hosp#:

Provider Group:

Date of Service:

Date Received:

Outpatient

Case #

A copy of this report will be faxed to:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - D.) RIGHT BREAST AND AXILLARY LYMPH NODES, MASTECTOMY WITH SENTINEL LYMPH NODE BIOPSIES:

- Invasive ductal carcinoma, Nottingham grade 1.
- Present in lower inner quadrant.
- Tumor size: 1.2 cm in diameter.
- Invasive carcinoma invades into dermis; carcinoma focally abuts but does not invade into pectoralis muscle.
- Ductal carcinoma in situ (DCIS), low to intermediate nuclear grade, cribriform-type, with comedo necrosis and calcifications.
- DCIS is present in the area of invasive carcinoma, as well as in the central breast tissue.
- * - Malignant phyllodes tumor. See comment.
- Phyllodes tumor size: 3.2 cm in diameter.
- Present in upper outer quadrant.
- The mastectomy margins are free of tumor.
- Invasive carcinoma is 0.5 cm from deep margin, and is at least 1 cm from all other margins.
- Phyllodes tumor is at least 1.5 cm from all margins.
- Micrometastatic carcinoma in one of two sentinel lymph nodes (1/2).
- Size of metastatic focus: 0.1 cm.
- Isolated tumor cells are found in the second lymph node.

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade (invasive): Invasive ductal carcinoma, Nottingham grade 1.

- Malignant phyllodes tumor also present.

Type and grade (in situ): DCIS, low to intermediate nuclear grade.

Primary tumor: pT1c.

Regional lymph nodes: pN1(mi).

Distant metastasis: Not applicable.

Stage: IB.

ICD-O-3
Tumor Phyllodes, malignant 9020/3
Site: Right Breast, LIT 656.3
Code: B90.9
QD 1/2/13

Case #:

Page 1

This report continues... (FINAL)

[page 2 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Lymphovascular invasion: Not identified.

Margin status: Negative.

COMMENT: The mastectomy specimen contains two separate neoplasms, a conventional low grade invasive ductal carcinoma in the lower inner quadrant, and a malignant phyllodes tumor in the upper outer quadrant.

Histologic features of malignancy in the phyllodes tumor include marked cytologic atypia of the stromal cells and frequent mitotic activity (in some areas sixteen mitoses per ten high power fields). The edge of the phyllodes tumor shows microscopic infiltration into the surrounding adipose tissue, but no grossly appreciable infiltration into the surrounding breast tissue is seen. No significant stromal overgrowth is identified.

The separately submitted superior margin and the separately submitted medial breast tissue (specimens C and D) contain no additional foci of neoplasia.

Intradepartmental consultation: concurs with the above diagnoses.

Invasive Breast Cancer Tumor Staging Information

AJCC Cancer Staging Handbook, 7th Ed., and CAP Protocol (revised

Previous pathology specimens [REDACTED] Staging information based on invasive ductal carcinoma.

Case #:

Page 2

This report continues... (FINAL)

[page 3 of 6]
Patient:

Case #:

SPECIMEN IDENTIFICATION

Procedure/specimen type:

Laterality:

Lymph node sampling:

Right mastectomy.

Right.

Sentinel lymph node biopsies.

INVASIVE CARCINOMA TUMOR CHARACTERISTICS

Histologic type:

Tumor site:

Tumor size:

Tumor focality:

Histologic grade (Nottingham Score):

Tubule formation:

Nuclear pleomorphism:

Mitotic rate:

Invasive ductal carcinoma. Malignant phyllodes tumor also present.

Lower inner quadrant.

1.2 cm.

Single focus invasive carcinoma.

1 of 3.

1 of 3.

1-2 of 3.

1 of 3.

Lymphovascular invasion:

Macroscopic and microscopic extent of tumor:

Indeterminate.

Invasive carcinoma invades into dermis by direct extension; tumor does not invade into pectoralis muscle.

DUCTAL CARCINOMA IN SITU (DCIS):

Low to intermediate grade DCIS with comedo necrosis, present in association with invasive carcinoma and extending into central breast.

MARGINS

Invasive carcinoma:

0.5 cm from deep margin, at least 1 cm from all other margins.

Ductal carcinoma in situ:

Phyllodes tumor:

At least 1 cm from all margins.

1.5 cm from deep margin, at least 1.5 cm from all other margins.

LYMPH NODES

Total lymph nodes examined

Number of lymph nodes involved

Size of largest metastatic deposit:

Extranodal extension:

Two.

One.

0.1 cm.

Not identified.

PATHOLOGIC STAGING:

Primary Tumor (pT):

Regional lymph nodes (pN):

Distant metastasis (pM):

AJCC Stage:

pT1c.

pN1(mi).

Not applicable.

IB.

ANCILLARY STUDIES:

Estrogen receptor:

Progesterone receptor:

ProPath

100% positive cells, strong intensity.

60% positive cells, strong intensity.

Case #:

Page 3

This report continues... (FINAL)

[page 4 of 6]
Patient:

Case #

FINAL SURGICAL PATHOLOGY REPORT

HER2:
Ki-67:

IHC score 0.
5% positive cells.

Source of Specimen:

- A. Sentinel lymph node;right axillary (200)
- B. Breast total mastectomy
- C. Additional superior right breast
- D. Medial right breast tissue

Clinical History/Operative Dx:

Malignant neoplasm of upper outer quadrant of female breast.

Intraoperative Diagnosis:

A. Sentinel node, right axillary, touch prep: Negative for metastasis. The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. Part A is labeled sentinel node #1, right axillary (200), touch prep. Initially received in the fresh state for touch prep analysis is a portion of yellow-tan fibrofatty soft tissue, 3.8 x 3.0 x 1.5 cm. Examination reveals two lymph node candidates, 3.5 and 2.0 cm each. The lymph nodes are serially sectioned demonstrating rubbery, light pink and tan cut surfaces without grossly discrete nodularity. Four touch preparation slides are forwarded for microscopic evaluation. The lymph node tissue is entirely submitted for routine histology with a sentinel node protocol performed.

Cassette summary:

A1-A3) largest lymph node,

Case #:

Page 4

This report continues... (FINAL)

[page 5 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

A4-A5) smallest lymph node.

B. The specimen is labeled right breast mastectomy tissue and is received without fixative. It consists of a mastectomy specimen weighing 490 grams. A black suture marks medial. With this orientation the specimen measures 23 cm from medial to lateral, 13 cm from superior to inferior, and is up to 3.8 cm from anterior to posterior. There is an overlying ellipse of tan skin which measures 20 x 12.5 cm. In the medial most portion of the skin there is a linear scar with a slight palpable firmness. This linear scar is 2 cm in length. It is 8 cm medial to the nipple. The skin is otherwise tan and unremarkable. The anterior-superior margin is inked blue, the anterior-inferior margin is inked green, and the posterior margin, which consists predominantly of smooth fascial tissue, is inked black. In the medial portion of the specimen, corresponding to the linear scar superficially, skeletal muscle is present at the deep margin and measures 2.5 x 2 cm.

The specimen is serially sectioned at close intervals to reveal a small stellate neoplasm in the lower inner quadrant. It measures 1.2 cm from medial to lateral, 0.9 cm from superior to inferior, and 0.8 cm from anterior to posterior. It causes dimpling of the skin and abuts the skeletal muscle at the deep edge of the neoplasm. The neoplasm is 0.5 cm from the closest deep margin which is the skeletal muscle, 1.7 cm from the closest inferior margin, 4 cm from the closest superior margin, 2.5 cm from the closest medial margin, and greater than 15 cm from the lateral margin.

In the upper and outer quadrant there is a relatively well circumscribed mass which is composed of slightly bulging glistening tan tissue. This mass measures 2.8 cm from medial to lateral, 3.2 cm from superior to inferior, and 3 cm from superficial to deep. Representative sections of the upper outer quadrant mass are obtained for research purposes. It is 0.7 cm from the closest margin which is the anterior-superior margin. It is 1.5 cm from the closest deep margin. It is 6.5 cm from the closest inferior margin, 3 cm from the closest lateral margin, and 12 cm from the closest medial margin. The remainder of the breast is composed of lobulated fatty tissue and predominantly centrally located fibrous parenchyma. The central fibrous parenchyma is moderately dense but no other areas have a stellate or retracted appearance. No lymph nodes are identified within the lateral portion of the excision.

Representative sections are submitted. Section summary:

B1) nipple and tissue deep to nipple,
B2-B6) deep margin of mastectomy specimen lower inner quadrant including skeletal muscle progressing from medial breast toward center of breast,
B7-B8) lower inner quadrant neoplasm and closest approach to skin,
B9-B10) upper outer quadrant mass and closest approach to anterior-superior margin,
B11-B15) representative sections of upper outer quadrant mass,
B16) deep surgical margin underlying upper outer quadrant mass,
B17) representative sections upper inner quadrant,
B18) lower inner quadrant,
B19) upper outer quadrant,
B20-B21) central breast

C. Part C is labeled additional superior margin over tumor, right breast. Received in formalin is a 12 gram ovoid pad of yellow-tan fibrofatty soft tissue, 5.7 cm medial-lateral, 3.4 cm posterior-anterior, and 1.1 cm

Case #:

Page 5

This report continues. (FINAL)

[page 6 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

old surface (blue)-superior surgical margin. Two sets of sutures are present; a short suture marks anterior-medial and a long suture marks anterior-lateral. The surgical margins are now differentially inked as follows:

Superior surface is marked blue,
Inferior (old surface) is over-inked green,
Anterior edge is marked yellow,
Posterior edge is marked black,
Medial edge is marked red,
Lateral edge is marked orange.

The specimen is serially sectioned perpendicularly through the medial-lateral long axis demonstrating glistening, lobular, yellow-tan fatty cut surfaces without discrete residual or invasive tumor component. The specimen is entirely submitted for microscopic evaluation in a sequential fashion, medial to lateral in C1-C9. ■

D. Part D is labeled as medial right breast tissue. Received in formalin is a flimsy pad of fibrofatty soft tissue weighing 8 grams and measuring 5.1 cm inferior-superior, 2.3 cm medial-lateral, and 2.1 cm anterior (blue)-posterior. A clip marks the medial edge and the anterior surface has been previously marked blue. The specimen is now differentially inked as follows:

Anterior is over-inked blue,
Posterior is inked black,
Medial periphery is marked red,
Lateral periphery is marked orange,
Inferior periphery is marked green,
Superior periphery is marked yellow.

The specimen is serially sectioned perpendicularly through the superior-inferior long axis to reveal glistening, yellow-tan fatty cut surfaces without gross residual/invasive tumor component. The specimen is entirely submitted for microscopic evaluation in a sequential fashion, superior to inferior, in A1-A6. ■

Microscopic Description:

A. Immunohistochemical stain: CK-OSCAR, highlighting micrometastasis in isolated tumor cells in axillary lymph nodes. Appropriate positive and negative controls reviewed.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Case #:

Page 6

END OF REPORT (FINAL)

Dual/Synchronous Primary Noted	breast axial	✓

Source: NCI Genomic Data Commons file 8d7bbd8f-29ce-40d2-9871-46bc6d872864 (TCGA-AC-A5EI.C0F7848A-DD0B-47B2-956F-A24D597D70BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).